Somatic mutation profile of tumor specimen 5c3971ee-87c7-4dff-b66e-f18892 (aliquot 5c3971ee-87c7-4dff-b66e-f18892_D6) from CPTAC case 02OV045, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 5c3971ee-87c7-4dff-b66e-f18892: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fa149b5-eb4c-4035-ad5a-c2d7eacd377b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b87e9510-8002-40d0-8079-f6b8f8 (Blood Derived Normal), aliquot b87e9510-8002-40d0-8079-f6b8f8_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7f03210-f81c-406d-9eab-55346be91d19

The open-access MAF lists 129 somatic variants for this specimen: 87 protein-altering or splice-affecting, 28 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Intron 8, Splice Site 7, Frame Shift Del 6, 5'UTR 3, In Frame Del 3, 3'UTR 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 284/437 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.8094C>G p.F2698L | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV54136027; called by muse, mutect2, varscan2
- C10orf90 | c.684C>A p.D228E | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as rs938927737, COSV99502827; called by muse, mutect2
- CA4 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 128/377 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.058); catalogued as COSV99039722; called by muse, mutect2, varscan2
- CCDC180 | c.4651G>T p.A1551S | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs759462679; called by muse, mutect2, varscan2
- CCR7 | c.548G>C p.W183S | Missense Mutation (SNP) | VAF 135/208 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367912385; called by muse, mutect2, varscan2
- DGLUCY | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.714); catalogued as COSV54088584; called by muse, mutect2, varscan2
- DOCK1 | c.2138+1G>A p.X713_splice | Splice Site (SNP) | VAF 23/73 reads (32%) | catalogued as rs747844641, COSV54753249; called by muse, mutect2, varscan2
- EDC4 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 166/395 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV62766186; called by muse, mutect2, varscan2
- EGFR | c.1431G>C p.W477C | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51805522; called by muse, mutect2, varscan2
- EPS15L1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1157609458; called by muse, mutect2, varscan2
- F5 | c.4552G>A p.D1518N | Missense Mutation (SNP) | VAF 132/590 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100889235; called by muse, varscan2
- FAM9C | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV61776120; called by muse, mutect2, varscan2
- FBXO43 | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.436); catalogued as rs768463614; called by muse, mutect2, varscan2
- KIAA1109 | c.7683G>T p.Q2561H | Missense Mutation (SNP) | VAF 149/407 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as COSV99145298, COSV99165148; called by muse, mutect2, varscan2
- KIF21B | c.1640A>G p.D547G | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1490617938; called by muse, mutect2, varscan2
- KLHL26 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as rs780012342, COSV56316490; called by muse, mutect2
- LRRC25 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 172/284 reads (61%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1276839320; called by muse, mutect2, varscan2
- OGFR | c.553C>G p.R185G | Missense Mutation (SNP) | VAF 114/414 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs755214349; called by muse, mutect2, varscan2
- PIEZO1 | c.559C>G p.R187G | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.253); catalogued as COSV56332927; called by muse, mutect2
- PRR12 | c.1956_1967del p.P654_P657del (on ENST00000615927; = p.P1475_P1478del on NM_020719.3) | In Frame Del (DEL) | VAF 27/46 reads (59%) | catalogued as rs920240724; called by mutect2, varscan2
- PRR16 | c.479C>A p.P160Q (on ENST00000407149 / NM_001300783.2; = p.P137Q on NM_016644.2) | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65395149, COSV65399812; called by muse, mutect2, varscan2
- SPHKAP | c.4786G>C p.G1596R (on ENST00000392056 / NM_001142644.2; = p.G1567R on NM_030623.3) | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100764071; called by muse, mutect2
- SYNE1 | c.12486G>C p.E4162D (on ENST00000367255 / NM_182961.4; = p.E4091D on NM_033071.3) | Missense Mutation (SNP) | VAF 210/554 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs769106802; called by muse, mutect2, varscan2
- ABLIM1 | c.2275G>C p.E759Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); called by muse, varscan2
- ACP5 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANKRD12 | c.508T>C p.S170P | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARFIP2 | c.526_537+16del p.X176_splice | Splice Site (DEL) | VAF 145/385 reads (38%) | called by mutect2, pindel, varscan2
- ATP11C | c.2837+2T>A p.X946_splice | Splice Site (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- BRCA1 | c.3040del p.M1014Wfs*10 | Frame Shift Del (DEL) | VAF 105/166 reads (63%) | called by mutect2, varscan2
- BRD1 | c.2017A>G p.I673V | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf47 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 97/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C4orf47 | c.833_864del p.G278Dfs*31 | Frame Shift Del (DEL) | VAF 31/56 reads (55%) | called by mutect2, pindel, varscan2
- CCDC142 | c.851_861del p.G284Vfs*61 | Frame Shift Del (DEL) | VAF 216/466 reads (46%) | called by mutect2, varscan2
- CCDC40 | c.248_268del p.A83_A89del | In Frame Del (DEL) | VAF 25/223 reads (11%) | called by mutect2, pindel
- CCDC80 | c.553_560del p.Q185Cfs*8 | Frame Shift Del (DEL) | VAF 98/612 reads (16%) | called by mutect2, pindel, varscan2
- CCR7 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 134/207 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCA4 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CLVS1 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 33/148 reads (22%) | called by muse, mutect2, varscan2
- COL17A1 | c.3735C>A p.S1245R | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- COL7A1 | c.6937-2A>C p.X2313_splice | Splice Site (SNP) | VAF 65/217 reads (30%) | called by muse, mutect2, varscan2
- COPE | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CPN1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 160/406 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DHX33 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DIS3 | c.2247G>C p.M749I | Missense Mutation (SNP) | VAF 89/137 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- DMXL1 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- FBXO10 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.324); called by muse, mutect2
- FMR1 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXK1 | c.1244+1G>T p.X415_splice | Splice Site (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- GATB | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GLB1L3 | c.1437G>T p.L479F | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- GPCPD1 | c.1977C>G p.I659M | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GRIK1 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 153/414 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IL6R | c.949+1G>A p.X317_splice | Splice Site (SNP) | VAF 41/115 reads (36%) | called by muse, mutect2, varscan2
- ITLN1 | c.686-1G>A p.X229_splice | Splice Site (SNP) | VAF 30/309 reads (10%) | called by muse, mutect2
- KIAA1109 | c.7682A>T p.Q2561L | Missense Mutation (SNP) | VAF 147/404 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LONP1 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.093); called by muse, mutect2
- LRRC24 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC37A | c.4339T>C p.Y1447H | Missense Mutation (SNP) | VAF 171/314 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LTBP1 | c.2116G>C p.V706L (on ENST00000404816 / NM_206943.4; = p.V380L on NM_000627.4) | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- NEUROD1 | c.582_598del p.F195Pfs*43 | Frame Shift Del (DEL) | VAF 85/324 reads (26%) | called by mutect2, pindel, varscan2
- NR5A1 | c.1225T>A p.Y409N | Missense Mutation (SNP) | VAF 204/577 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSCN | c.1702T>C p.W568R | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2J1 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 152/196 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5K1 | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 126/318 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PDE1C | c.1684G>C p.G562R | Missense Mutation (SNP) | VAF 119/384 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLB1 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSIP1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PSMC3 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- RASGEF1C | c.595A>C p.S199R | Missense Mutation (SNP) | VAF 360/797 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- RFPL3 | c.83_116del p.V28Afs*58 | Frame Shift Del (DEL) | VAF 41/90 reads (46%) | called by mutect2, pindel, varscan2
- RNF111 | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RNF26 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 29/628 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- SCARF2 | c.2028G>T p.K676N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.705); called by muse, varscan2
- SCFD1 | c.200A>G p.D67G | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SEC24D | c.2493C>A p.S831R | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- SH3BP5 | c.91A>T p.M31L | Missense Mutation (SNP) | VAF 99/144 reads (69%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); called by muse, varscan2
- SLC25A25 | c.266G>C p.S89T | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- STYXL2 | c.1960A>C p.S654R | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2
- TTPA | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBR2 | c.882G>C p.Q294H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- UPF3B | c.24G>T p.R8S | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WDR33 | c.3335A>C p.H1112P | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR81 | c.5348G>T p.G1783V (on ENST00000409644 / NM_001163809.2; = p.G732V on NM_152348.4) | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- ZBTB33 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX3 | c.9155_9160del p.V3052_K3053del | In Frame Del (DEL) | VAF 56/660 reads (8%) | called by mutect2, pindel
- ZNF821 | c.933G>T p.E311D (on ENST00000425432 / NM_001376297.1; = p.E269D on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 174/391 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ADD2 | c.396C>G p.L132= | Silent (SNP) | VAF 95/277 reads (34%) | catalogued as rs376988741; called by muse, mutect2, varscan2
- ARFGEF3 | c.1875C>T p.S625= | Silent (SNP) | VAF 36/423 reads (9%) | catalogued as rs750572567; called by muse, mutect2
- ASF1B | c.34C>T p.L12= | Silent (SNP) | VAF 111/187 reads (59%) | called by muse, mutect2, varscan2
- BICRA | c.246G>T p.L82= | Silent (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2148C>A p.V716= (on ENST00000356253 / NM_001366867.1; = p.V704= on NM_000722.4) | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- CPLANE1 | c.8808T>A p.T2936= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- CREBZF | c.687G>A p.V229= | Silent (SNP) | VAF 126/467 reads (27%) | catalogued as rs1352793774; called by muse, mutect2, varscan2
- CYP2W1 | c.543G>A p.A181= | Silent (SNP) | VAF 51/405 reads (13%) | catalogued as rs762405080; called by muse, mutect2, varscan2
- DENND1C | c.864G>A p.L288= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs1226328692; called by muse, mutect2, varscan2
- DSC3 | c.2034T>C p.R678= | Silent (SNP) | VAF 11/294 reads (4%) | called by muse, mutect2
- FERMT2 | c.405C>G p.P135= | Silent (SNP) | VAF 42/112 reads (38%) | called by muse, mutect2, varscan2
- GPR162 | c.78G>A p.L26= | Silent (SNP) | VAF 91/140 reads (65%) | catalogued as rs1565507256; called by muse, mutect2, varscan2
- GRIK2 | c.891G>T p.S297= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as COSV59755073; called by muse, mutect2, varscan2
- HIVEP3 | c.5463C>T p.A1821= | Silent (SNP) | VAF 92/307 reads (30%) | catalogued as rs1279057683, COSV99912007; called by muse, mutect2, varscan2
- KHDRBS3 | c.1026A>T p.P342= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- KRT3 | c.1674C>A p.G558= | Silent (SNP) | VAF 87/257 reads (34%) | called by muse, mutect2, varscan2
- MUC4 | c.12762G>C p.S4254= | Silent (SNP) | VAF 61/201 reads (30%) | catalogued as rs550434908, COSV57771965; called by muse, mutect2, varscan2
- MYO7B | c.30G>T p.V10= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- NLGN3 | c.357G>A p.L119= | Silent (SNP) | VAF 259/558 reads (46%) | called by mutect2, varscan2
- NTRK2 | c.486C>G p.L162= | Silent (SNP) | VAF 74/545 reads (14%) | called by muse, mutect2, varscan2
- PPM1A | c.76C>T p.L26= | Silent (SNP) | VAF 91/218 reads (42%) | called by muse, mutect2, varscan2
- RFX1 | c.2358G>A p.V786= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2
- RNF166 | c.384C>A p.P128= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV100455504; called by muse, mutect2, varscan2
- SH3PXD2A | c.2283C>T p.F761= (on ENST00000369774 / NM_001365079.1; = p.F733= on NM_014631.2) | Silent (SNP) | VAF 115/345 reads (33%) | called by muse, mutect2, varscan2
- SPRR2E | c.33C>A p.P11= | Silent (SNP) | VAF 100/374 reads (27%) | called by muse, varscan2
- TH | c.1014G>T p.V338= (on ENST00000381178 / NM_199292.3; = p.V307= on NM_000360.4) | Silent (SNP) | VAF 89/235 reads (38%) | called by muse, mutect2, varscan2
- USH1C | c.951T>A p.L317= | Silent (SNP) | VAF 222/585 reads (38%) | called by muse, mutect2, varscan2
- ZFAND1 | c.66A>T p.P22= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- ABCC8 | c.-40G>T | 5'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- CDH11 | c.1895-603T>A | Intron (SNP) | VAF 70/167 reads (42%) | called by muse, mutect2, varscan2
- CPEB1 | c.371-1620C>G | Intron (SNP) | VAF 41/50 reads (82%) | catalogued as rs1204451225; called by muse, mutect2, varscan2
- CROCC2 | c.*27G>A | 3'UTR (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- CTIF | c.180+1888C>A | Intron (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- CXADRP2 | n.636G>C | RNA (SNP) | VAF 83/317 reads (26%) | called by muse, mutect2, varscan2
- ESR1 | c.-41C>A | 5'UTR (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- FANCF | c.*42C>G | 3'UTR (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- JMJD6 | c.941+493G>C | Intron (SNP) | VAF 34/49 reads (69%) | called by muse, mutect2, varscan2
- KIAA0895L | c.848-344G>T | Intron (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- KMT2A | c.11063-24C>T | Intron (SNP) | VAF 101/135 reads (75%) | catalogued as rs111313792; called by muse, mutect2, varscan2
- LRP3 | c.476-79G>A | Intron (SNP) | VAF 47/124 reads (38%) | catalogued as rs760604412; called by muse, mutect2, varscan2
- POLR3C | c.1324-17G>A | Intron (SNP) | VAF 61/154 reads (40%) | called by muse, mutect2, varscan2
- ZFP36L1 | c.-51G>C | 5'UTR (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
